Somatic mutation profile of tumor specimen TCGA-B6-A0X4-01A (aliquot TCGA-B6-A0X4-01A-11D-A10G-09) from TCGA case TCGA-B6-A0X4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.1 years (22,688 days).
Specimen TCGA-B6-A0X4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f47695d9-c525-492b-8c75-91fc34a47556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0X4-10A (Blood Derived Normal), aliquot TCGA-B6-A0X4-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39eedeaf-7668-4813-9ab1-26e7b80e3c92

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 4, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 82/202 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2, varscan2
- ATAD2 | c.2481T>G p.I827M | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99785520; called by muse, mutect2, varscan2
- ATP8B2 | c.418G>A p.D140N (on ENST00000672630; = p.D107N on NM_001005855.2) | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59249294; called by muse, mutect2, varscan2
- CYP4Z1 | c.176A>C p.E59A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV61966889; called by muse, mutect2, varscan2
- DLK1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs146800507; called by muse, mutect2, varscan2
- GRIK2 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as rs140472463, COSV59713627; called by muse, varscan2
- KCTD3 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV52071117; called by muse, mutect2, varscan2
- KMT2C | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV51507636; called by muse, mutect2, varscan2
- MUC16 | c.39688G>A p.G13230R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as rs746951194, COSV66697032; called by muse, mutect2, varscan2
- RNF217 | c.1378C>T p.R460* (on ENST00000521654 / NM_001286398.2; = p.R168* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 50/111 reads (45%) | catalogued as rs777059419, COSV51577839; called by muse, mutect2, varscan2
- SACS | c.8262G>T p.K2754N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66546472; called by muse, mutect2, varscan2
- SLC22A25 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1238485866, COSV60599692; called by muse, mutect2, varscan2
- VIL1 | c.2065C>A p.R689S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50299047; called by muse, mutect2, varscan2
- WDR3 | c.1462C>A p.L488M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV62525498; called by muse, mutect2, varscan2
- ZNF229 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as rs377446964, COSV52163535, COSV52165500; called by muse, mutect2, varscan2
- GSE1 | c.3349del p.E1117Kfs*21 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- FCGR2B | c.312C>T p.N104= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52683339; called by muse, mutect2, varscan2
- IFT80 | c.306A>T p.V102= | Silent (SNP) | VAF 82/222 reads (37%) | catalogued as COSV58452900; called by muse, mutect2, varscan2
- SSR4 | c.429C>T p.N143= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV51252170; called by muse, mutect2, varscan2
- TUBB7P | n.1222A>G | RNA (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
